National Lung Screening Trial (NLST) participant 213034 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 62 years; Gender: male; Race: Black or African-American; Cigarette smoking status at randomisation: current smoker; Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Lung cancer (2 primary lung cancer records; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 128, study year T0. Site: lower lobe of lung (ICD-O-3 C34.3), determined from histology. Primary tumour location: right lower lobe. Histology: adenosquamous carcinoma (ICD-O-3 8560/3). Tumour size on pathology: 20 mm. AJCC 6th edition staging: stage IA (best stage, from pathologic TNM); clinical T1 NX MX; pathologic T1 N0 M0 (stage IA). AJCC 7th edition staging: stage IA; clinical T1a NX MX; pathologic T1a N0 M0. Summary stage: localized.
2. Subsequent primary lung cancer, diagnosed day 1,701, study year T4. Site: upper lobe of lung (ICD-O-3 C34.1), determined from histology. Histology: adenocarcinoma, NOS (ICD-O-3 8140/3). Grade: moderately differentiated (G2). Tumour size on pathology: 20 mm. AJCC 6th edition staging: stage IA (best stage, from a mixture of clinical and pathologic TNM components); clinical T1 N0 M0 (stage IA); pathologic T1 NX MX. Summary stage: localized.

Follow-up
Last known free of lung cancer: day 128 (for ACRIN participants with lung cancer this field holds the diagnosis date).
